Somatic mutation profile of tumor specimen C3L-02669-01 (aliquot CPT0202350007) from CPTAC case C3L-02669, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 73.3 years (26,778 days).
Specimen C3L-02669-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 817b2f98-c4b6-4e51-b9ba-4d0fedebab63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02669-31 (Blood Derived Normal), aliquot CPT0202510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/662593b8-3196-466f-a442-3d78a39cc837

The open-access MAF lists 708 somatic variants for this specimen: 473 protein-altering or splice-affecting, 153 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 393, Silent 153, Nonsense Mutation 38, Intron 34, Splice Site 17, RNA 15, Frame Shift Del 13, 3'UTR 13, 5'Flank 10, Splice Region 7, 5'UTR 6, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>T p.X307_splice | Splice Site (SNP) | VAF 74/210 reads (35%) | hotspot (GDC flag); catalogued as COSV52693974, COSV52706655, COSV52945558, COSV53066011; called by muse, mutect2, varscan2
- TPP1 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 53/386 reads (14%) | catalogued as rs1184563885, CM001073; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1001+1G>T p.X334_splice | Splice Site (SNP) | VAF 43/169 reads (25%) | catalogued as COSV100088752; called by muse, mutect2, varscan2
- ACTRT1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV64419592; called by muse, mutect2, varscan2
- ADAM9 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391707156; called by muse, mutect2, varscan2
- ADCY8 | c.2631C>A p.Y877* | Nonsense Mutation (SNP) | VAF 42/224 reads (19%) | catalogued as COSV53898678, COSV53913133; called by muse, varscan2
- AMPH | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57737817; called by muse, mutect2, varscan2
- ANKRD18A | c.2205C>G p.D735E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.935); catalogued as COSV68802568; called by muse, mutect2, varscan2
- ANKRD30A | c.2015C>A p.P672Q (on ENST00000611781; = p.P616Q on NM_052997.2) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.954); catalogued as rs971649198; called by muse, mutect2, varscan2
- AR | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.067); catalogued as rs1364038551; called by muse, mutect2, varscan2
- ARAP3 | c.4030C>T p.Q1344* | Nonsense Mutation (SNP) | VAF 59/373 reads (16%) | catalogued as COSV53353898; called by muse, mutect2, varscan2
- ARFGAP3 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs748596047, COSV54312799; called by muse, mutect2, varscan2
- ARHGAP28 | c.543+1G>T p.X181_splice (on ENST00000383472 / NM_001366230.1; = p.X22_splice on NM_001010000.3) | Splice Site (SNP) | VAF 18/104 reads (17%) | catalogued as rs1219321054, COSV99151083; called by muse, mutect2
- ARHGAP30 | c.1333C>A p.R445S | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100920115, COSV100920193; called by muse, mutect2, varscan2
- ASTN1 | c.1451G>A p.C484Y | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56079543; called by muse, mutect2, varscan2
- ATP10B | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747886452; called by muse, mutect2, varscan2
- ATP12A | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967156411; called by muse, mutect2
- ATP1A4 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63628690; called by muse, mutect2, varscan2
- ATP6V1A | c.839del p.R280Kfs*23 | Frame Shift Del (DEL) | VAF 45/386 reads (12%) | catalogued as COSV56360821; called by mutect2, pindel, varscan2
- BIRC6 | c.11669A>G p.D3890G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as rs1298934043; called by muse, mutect2, varscan2
- BMPER | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV51827466; called by muse, mutect2, varscan2
- C19orf81 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as COSV53262596; called by muse, mutect2, varscan2
- CAPS2 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs1246472516; called by muse, mutect2, varscan2
- CAVIN4 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); catalogued as COSV56866801; called by muse, mutect2, varscan2
- CCAR1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 9/106 reads (8%) | catalogued as COSV56273341; called by muse, mutect2
- CDCA7L | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651281; called by muse, mutect2, varscan2
- CDH10 | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232692431; called by muse, mutect2, varscan2
- CDKN2A | c.304del p.A102Rfs*44 | Frame Shift Del (DEL) | VAF 148/684 reads (22%) | catalogued as rs774904310, CM056559, COSV58704200, COSV58708391; called by mutect2, pindel, varscan2
- CFAP46 | c.7295C>T p.T2432I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV54149250; called by muse, mutect2, varscan2
- CFH | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1558155754; called by muse, mutect2, varscan2
- CHD8 | c.2629G>A p.E877K (on ENST00000646647 / NM_001170629.2; = p.E598K on NM_020920.4) | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101303029; called by muse, mutect2, varscan2
- CNTN4 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs757475566; called by muse, mutect2, varscan2
- CNTNAP2 | c.2153G>T p.W718L | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124268, CM116365; called by muse, mutect2, varscan2
- CSF2RA | c.441C>A p.D147E | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100817964; called by muse, mutect2, varscan2
- CSMD3 | c.10748C>A p.A3583D (on ENST00000297405 / NM_001363185.1; = p.A3414D on NM_052900.3) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99819745; called by muse, mutect2
- CTNNA2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV58169685; called by muse, mutect2, varscan2
- CTNNA3 | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781257513, COSV65558798; called by muse, mutect2, varscan2
- CTNND2 | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 40/266 reads (15%) | catalogued as COSV58928509; called by muse, mutect2, varscan2
- DCC | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV59104186; called by muse, mutect2, varscan2
- DDX17 | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53254130; called by muse, mutect2, varscan2
- DMBT1 | c.2137+1G>A p.X713_splice | Splice Site (SNP) | VAF 52/282 reads (18%) | catalogued as rs1262906144; called by muse, mutect2, varscan2
- DNAI4 | c.2113-1G>A p.X705_splice | Splice Site (SNP) | VAF 7/124 reads (6%) | catalogued as COSV64030299; called by muse, mutect2
- DOCK10 | c.4507-2A>G p.X1503_splice | Splice Site (SNP) | VAF 28/110 reads (25%) | catalogued as rs1398598150; called by muse, mutect2, varscan2
- DRGX | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65136683; called by muse, mutect2, varscan2
- ECHS1 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as rs587776498, CM151093, COSV100881892; called by muse, mutect2, varscan2
- EGFLAM | c.2489C>G p.T830R (on ENST00000354891 / NM_001205301.2; = p.A822G on NM_152403.4) | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV59314388; called by muse, mutect2, varscan2
- ELAVL1 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs1294906748, COSV60967592; called by muse, mutect2, varscan2
- ENOX1 | c.891del p.R298Afs*20 | Frame Shift Del (DEL) | VAF 51/380 reads (13%) | catalogued as COSV54920382; called by mutect2, pindel, varscan2
- ENPP2 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as rs1252523976, COSV50013610; called by muse, varscan2
- EP400 | c.1829A>G p.Q610R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.528); catalogued as COSV100200788; called by muse, mutect2, varscan2
- EPHA3 | c.2005G>T p.G669* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV60709211; called by muse, mutect2, varscan2
- ESPL1 | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs767677452; called by muse, mutect2, varscan2
- F13A1 | c.567T>A p.C189* | Nonsense Mutation (SNP) | VAF 43/286 reads (15%) | catalogued as CM1313708; called by muse, mutect2, varscan2
- F8 | c.1631A>T p.D544V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1414432; called by muse, mutect2, varscan2
- FAM135B | c.3887T>A p.L1296Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716352; called by muse, mutect2, varscan2
- FAM189A1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231973920; called by muse, mutect2, varscan2
- FBN2 | c.2480G>C p.R827P | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52512855; called by muse, mutect2, varscan2
- FCGBP | c.10889C>T p.A3630V | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs376528459; called by muse, mutect2, varscan2
- FLG | c.7613C>T p.S2538F | Missense Mutation (SNP) | VAF 84/637 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs530424264; called by muse, mutect2, varscan2
- GABRG1 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54952155; called by muse, mutect2, varscan2
- GALNT17 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61177667; called by muse, mutect2
- GCFC2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 22/163 reads (13%) | catalogued as rs766186523; called by muse, mutect2, varscan2
- GIMAP2 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV99785502; called by muse, mutect2
- GLI2 | c.4027G>C p.G1343R (on ENST00000361492 / NM_001374353.1; = p.G1360R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs977003501; called by muse, mutect2, varscan2
- GPAT3 | c.1126-8T>A | Splice Region (SNP) | VAF 24/131 reads (18%) | catalogued as rs778710679, COSV104388434; called by muse, mutect2, varscan2
- GRID2 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56202556, COSV99945884; called by muse, mutect2, varscan2
- GRM8 | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58853689; called by muse, mutect2, varscan2
- H2BC5 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as rs778040224, COSV56803659; called by muse, mutect2, varscan2
- H3C2 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV99451632; called by muse, mutect2, varscan2
- HHAT | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV99803203; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57134311; called by muse, mutect2, varscan2
- KCNA3 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs775396919; called by muse, mutect2, varscan2
- KCNH7 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | catalogued as COSV59812819; called by muse, mutect2, varscan2
- KCNK15 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs774071891; called by mutect2, varscan2
- KCP | c.890C>G p.P297R (on ENST00000620378; = p.P354R on NM_001366122.1) | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571789943; called by muse, mutect2, varscan2
- LAIR2 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1241680217, COSV56620663; called by muse, varscan2
- LAMA2 | c.640-1G>T p.X214_splice | Splice Site (SNP) | VAF 25/135 reads (19%) | catalogued as rs1296761337, CS151378; called by muse, mutect2, varscan2
- LRFN3 | c.1802C>A p.P601Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.418); catalogued as COSV99873698; called by muse, mutect2, varscan2
- LRP1B | c.8858G>T p.C2953F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748907032, COSV67186469; called by muse, mutect2, varscan2
- LRRC14 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.262); catalogued as COSV52880048; called by muse, mutect2, varscan2
- LRRIQ3 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63049938; called by mutect2, varscan2
- MAML3 | c.1643A>T p.N548I | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59076422; called by muse, mutect2, varscan2
- MAP3K21 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV100786290; called by muse, mutect2, varscan2
- MMP16 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV54154998; called by muse, mutect2, varscan2
- MRPL33 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs763582483, COSV56088034; called by muse, mutect2, varscan2
- MUC4 | c.2815C>A p.P939T | Missense Mutation (SNP) | VAF 84/487 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.65); catalogued as rs373436111; called by muse, mutect2, varscan2
- MYH4 | c.3704T>A p.L1235H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV55119360; called by muse, mutect2, varscan2
- MYH4 | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV55123094; called by muse, mutect2, varscan2
- MYH4 | c.2760G>T p.E920D | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV99702271; called by muse, mutect2, varscan2
- NALCN | c.4078G>A p.V1360M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74807744, COSV99213452; called by muse, mutect2, varscan2
- NCAPD3 | c.4222G>T p.V1408L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV73187866; called by muse, mutect2, varscan2
- NEO1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs766815523; called by muse, mutect2, varscan2
- NFE2L2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960111, COSV67960209, COSV67962392; called by muse, varscan2
- NOTCH1 | c.2047G>C p.A683P | Missense Mutation (SNP) | VAF 37/867 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as CM083741, COSV53072523; called by muse, mutect2
- NUP98 | c.1464G>T p.L488F | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100262543; called by muse, mutect2, varscan2
- OBSL1 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99217661; called by muse, mutect2, varscan2
- OR2G6 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV58573927; called by muse, mutect2, varscan2
- OR4P4 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV58921797; called by muse, mutect2, varscan2
- OR5AU1 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs1566572325, COSV58615765; called by muse, mutect2, varscan2
- OTOR | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55721619, COSV55721633; called by muse, mutect2, varscan2
- OXTR | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs752877652; called by muse, mutect2, varscan2
- P2RX4 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.141); catalogued as COSV100078734; called by muse, mutect2, varscan2
- PAX6 | c.1069A>G p.M357V | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV53795931; called by muse, mutect2, varscan2
- PCDHGA2 | c.2096C>A p.A699E | Missense Mutation (SNP) | VAF 99/510 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV54040233; called by muse, mutect2, varscan2
- PCDHGA7 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1252058358, COSV53938000, COSV99535011; called by muse, mutect2, varscan2
- PCLO | c.7944T>G p.F2648L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61648490; called by muse, mutect2, varscan2
- PLB1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs775547690; called by muse, mutect2
- PLEKHA3 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV99317729; called by muse, mutect2, varscan2
- PPP4R4 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 7/144 reads (5%) | catalogued as COSV58555917; called by muse, mutect2
- REST | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58360170; called by muse, mutect2, varscan2
- RYR3 | c.8477A>G p.Y2826C (on ENST00000389232; = p.Y2827C on NM_001036.6) | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs1476462565; called by muse, mutect2, varscan2
- SCPEP1 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs1454082464; called by muse, mutect2, varscan2
- SEC16A | c.6970del p.A2324Pfs*22 | Frame Shift Del (DEL) | VAF 43/254 reads (17%) | catalogued as COSV51533127; called by mutect2, pindel, varscan2
- SERPINA12 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs200196811; called by muse, mutect2, varscan2
- SFTPD | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100954508; called by muse, mutect2, varscan2
- SGTB | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV101121566; called by muse, mutect2, varscan2
- SHPRH | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs376399451, COSV99262193; called by muse, varscan2
- SLC12A2 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs925779744; called by muse, mutect2
- SLC17A7 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55549614, COSV55549814; called by muse, mutect2, varscan2
- SLC26A7 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs771201365; called by muse, mutect2, varscan2
- SLC27A1 | c.165C>G p.L55= | Splice Region (SNP) | VAF 34/184 reads (18%) | catalogued as rs1179347027, COSV99393046, COSV99393774; called by muse, mutect2
- SLC2A3 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV50000080; called by muse, varscan2
- SMG1 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 27/516 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs200419100; called by muse, mutect2
- SPAG6 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1314429426; called by muse, mutect2, varscan2
- SRSF12 | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV71683739; called by muse, mutect2, varscan2
- ST8SIA2 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 77/320 reads (24%) | PolyPhen probably damaging (0.998); catalogued as rs760014109; called by muse, mutect2, varscan2
- STEAP4 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57328845; called by muse, mutect2
- SUGT1P4-STRA6LP | n.1320G>C | Splice Region (SNP) | VAF 25/96 reads (26%) | catalogued as rs776499766; called by muse, mutect2, varscan2
- SV2C | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59218545; called by muse, mutect2, varscan2
- SVIL | c.2698C>G p.L900V (on ENST00000355867 / NM_021738.3; = p.L474V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100881390; called by muse, mutect2, varscan2
- SYNM | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs367761964; called by muse, mutect2, varscan2
- TET3 | c.3838G>T p.A1280S | Missense Mutation (SNP) | VAF 91/571 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as rs369960930; called by muse, mutect2, varscan2
- THBS2 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1458923611; called by muse, mutect2, varscan2
- THSD7A | c.3466A>G p.R1156G | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1023305180; called by muse, varscan2
- TJP1 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs747859807, COSV100632126; called by muse, mutect2, varscan2
- TMCC1 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 220/358 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as rs889797500; called by muse, mutect2, varscan2
- TMEM222 | c.195-2A>C p.X65_splice | Splice Site (SNP) | VAF 42/125 reads (34%) | catalogued as COSV65027269; called by muse, mutect2, varscan2
- TMEM87B | c.1377-2A>G p.X459_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as rs751828387; called by muse, mutect2, varscan2
- TPRG1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV61468507; called by muse, mutect2, varscan2
- TRIM59 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs375673052; called by muse, mutect2
- TTN | c.26737G>A p.G8913R (on ENST00000591111; = p.G7986R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/176 reads (14%) | PolyPhen probably damaging (0.964); catalogued as COSV60064117; called by muse, mutect2, varscan2
- UNC13C | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs868526038, COSV52928618; called by muse, mutect2, varscan2
- USHBP1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV53102260; called by muse, mutect2
- USP13 | c.2450C>T p.T817I | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1364948440; called by muse, mutect2, varscan2
- VN1R4 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99081906; called by muse, mutect2, varscan2
- XIRP2 | c.4283C>A p.A1428D (on ENST00000628543; = p.A1603D on NM_152381.6) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs74627077, COSV54728582; called by muse, mutect2, varscan2
- ZMAT1 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65657703; called by muse, mutect2, varscan2
- ZNF157 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs777442214; called by muse, mutect2, varscan2
- ZNF473 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs754568465, COSV54525448; called by muse, mutect2, varscan2
- ZNF493 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV62749625; called by muse, mutect2, varscan2
- ZNF521 | c.1384G>C p.A462P | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100831384; called by muse, mutect2, varscan2
- ZNF536 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV62828165, COSV62834837; called by muse, mutect2, varscan2
- ZNF665 | c.1777C>T p.Q593* (on ENST00000600412; = p.Q658* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs1392814787, COSV67213831; called by muse, mutect2, varscan2
- ZNF677 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762118209; called by muse, varscan2
- ZNF782 | c.1468A>G p.M490V | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV100001756; called by muse, mutect2, varscan2
- ABCA8 | c.4372T>A p.C1458S | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC053503.6 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- AC098582.1 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- AC138647.1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ACLY | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ADAMTS12 | c.2250dup p.Y751Ifs*16 | Frame Shift Ins (INS) | VAF 38/369 reads (10%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2662G>T p.G888* | Nonsense Mutation (SNP) | VAF 39/177 reads (22%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.2326del p.Q776Sfs*98 | Frame Shift Del (DEL) | VAF 78/472 reads (17%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.4255A>C p.T1419P (on ENST00000506720 / NM_001322402.2; = p.T1308P on NM_015236.6) | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL645922.1 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 99/526 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ALG10 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- AMER2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AMFR | c.1292G>T p.S431I | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- AOC1 | c.1765C>A p.H589N | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by mutect2, varscan2
- APEX1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- APOH | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ARHGAP45 | c.93G>A p.E31= | Splice Region (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- ATOH1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP10A | c.2373G>T p.K791N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AUTS2 | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BABAM1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- BAZ2B | c.4670G>A p.R1557K | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- BHMT2 | c.1010+2T>A p.X337_splice | Splice Site (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- BPIFB1 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- BRINP3 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CAB39L | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1G | c.3432G>C p.E1144D | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC14 | c.203C>T p.P68L (on ENST00000488653; = p.P20L on NM_022757.5) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC54 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCHCR1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CCM2L | c.325A>C p.S109R | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CD53 | c.9G>C p.M3I | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH10 | c.1037T>A p.L346Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH18 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH9 | c.2237T>A p.I746K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CDHR1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP100 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP221 | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFAP46 | c.2449C>A p.H817N | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CFHR4 | c.404A>G p.Q135R (on ENST00000367416 / NM_001201551.2; = p.Q136R on NM_001201550.3) | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.153); called by muse, mutect2
- CLPP | c.718A>C p.I240L | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CNGA4 | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, varscan2
- CNNM4 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- COL11A2 | c.2729G>T p.G910V (on ENST00000341947 / NM_080680.3; = p.G803V on NM_080679.2) | Missense Mutation (SNP) | VAF 122/698 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL2A1 | c.3117C>A p.S1039R | Missense Mutation (SNP) | VAF 82/423 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A1 | c.4022-1G>T p.X1341_splice | Splice Site (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- COL6A5 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 225/394 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- COL8A1 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CPD | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CR2 | c.1592del p.P531Lfs*13 | Frame Shift Del (DEL) | VAF 39/268 reads (15%) | called by mutect2, pindel, varscan2
- CRACDL | c.1817T>A p.V606D | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CREBBP | c.2995A>T p.T999S | Missense Mutation (SNP) | VAF 99/546 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSH2 | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 116/920 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CSPG4 | c.4871G>T p.R1624L | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CTTN | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 34/894 reads (4%) | called by muse, mutect2
- CYP4F22 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 100/487 reads (21%) | called by muse, mutect2, varscan2
- DBX1 | c.897C>A p.H299Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, varscan2
- DCLK1 | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DDR1 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DEFB115 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHRS3 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 55/218 reads (25%) | called by muse, mutect2, varscan2
- DHX15 | c.1385G>T p.S462I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLC1 | c.2027T>A p.L676H (on ENST00000276297 / NM_001348081.2; = p.L239H on NM_006094.5) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DMKN | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DMP1 | c.337A>C p.T113P | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.3530T>C p.L1177P | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH2 | c.5615T>A p.I1872N | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.11359G>T p.G3787* | Nonsense Mutation (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- DOCK8 | c.2683C>A p.L895M | Missense Mutation (SNP) | VAF 102/391 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DOT1L | c.2660G>T p.S887I | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- DPP4 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPYS | c.908C>G p.P303R | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DUSP13 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 46/187 reads (25%) | called by muse, mutect2, varscan2
- EEPD1 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHMT1 | c.3461+5G>A | Splice Region (SNP) | VAF 59/327 reads (18%) | called by muse, mutect2, varscan2
- ELP4 | c.1040-4C>G | Splice Region (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- EML3 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ERCC6 | c.3937A>T p.T1313S | Missense Mutation (SNP) | VAF 123/531 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- EYS | c.2696G>T p.C899F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM120A | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FAP | c.2094C>A p.H698Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.4954C>T p.P1652S | Missense Mutation (SNP) | VAF 40/465 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FGB | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FH | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.289); called by muse, mutect2
- FKBP8 | c.683G>T p.G228V (on ENST00000222308 / NM_001308373.2; = p.G229V on NM_012181.5) | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXD4L5 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by mutect2, varscan2
- FOXJ2 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2C | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- FRMPD3 | c.3479C>A p.A1160D | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FSTL1 | c.227A>T p.H76L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GABBR1 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GGA2 | c.1657A>C p.K553Q | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GGPS1 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLT1D1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1581G>A p.W527* | Nonsense Mutation (SNP) | VAF 70/390 reads (18%) | called by mutect2, varscan2
- GPR179 | c.3954G>C p.Q1318H (on ENST00000621958; = p.Q1317H on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2
- GPSM1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- GRIA2 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.094); called by muse, mutect2
- GRN | c.1192T>A p.S398T | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- GTF3C3 | c.2414G>C p.S805T | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- H2AC20 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 147/834 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H3C8 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDGF | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HEATR9 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- HELZ2 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HGSNAT | c.1802A>G p.D601G | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HHIPL2 | c.2077del p.H693Tfs*11 | Frame Shift Del (DEL) | VAF 75/531 reads (14%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.6928G>A p.E2310K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HMCN1 | c.4308T>G p.I1436M | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- HRH2 | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- HSPA4L | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- ICE1 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- ICMT | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- IDNK | c.51A>G p.K17= | Splice Region (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- IGKV1-9 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGSF9 | c.2369+1G>T p.X790_splice (on ENST00000368094 / NM_001135050.2; = p.X774_splice on NM_020789.4) | Splice Site (SNP) | VAF 51/336 reads (15%) | called by muse, mutect2, varscan2
- INSR | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IQUB | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ITIH5 | c.1181dup p.D395Rfs*83 | Frame Shift Ins (INS) | VAF 54/332 reads (16%) | called by pindel, varscan2
- ITK | c.788T>A p.M263K | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- JRK | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KCNG3 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KCNN4 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 90/525 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCTD12 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIAA1586 | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF20B | c.2857A>T p.K953* (on ENST00000371728 / NM_001284259.2; = p.K913* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- KLHL1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRC1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- KRTAP10-9 | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 143/555 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- LATS2 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCOR | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LILRB2 | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LIX1L | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); called by muse, mutect2
- LNX2 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 54/402 reads (13%) | called by muse, mutect2, varscan2
- LPCAT4 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRP1B | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- LRP2 | c.11981G>T p.G3994V | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.11980G>A p.G3994R | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.053); called by muse, varscan2
- MAGEL2 | c.2576C>A p.A859E | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAGEL2 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAN1A1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC2R | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCM9 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MED13L | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MEF2C | c.1323C>A p.N441K | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MEIS2 | c.128del p.P43Rfs*31 (on ENST00000561208 / NM_170675.5; = p.P30Rfs*31 on NM_002399.3) | Frame Shift Del (DEL) | VAF 21/200 reads (11%) | called by mutect2, pindel, varscan2
- MINAR1 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MKRN3 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MMRN1 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMRN1 | c.3252T>A p.N1084K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MPI | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 63/409 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MROH7 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTMR14 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- MTMR4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MTUS1 | c.1669C>G p.P557A | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTUS1 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MUC19 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MUC7 | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NANP | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAV3 | c.3040+1G>T p.X1014_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | called by muse, varscan2
- NCR3LG1 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2
- NDUFAF1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- NEBL | c.1485A>T p.K495N | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- NLGN1 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NPAP1 | c.1789G>C p.V597L | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NPHS1 | c.1429A>T p.M477L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OCA2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 90/454 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR1D5 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.029); called by mutect2, varscan2
- OR2L5 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- OR2T3 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2T34 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2T8 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OR4C3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR4E2 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4K5 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR51I2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51M1 | c.738G>C p.Q246H | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5AN1 | c.174del p.M60Cfs*11 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- OR8K3 | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- OR9G1 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2
- OXER1 | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- P2RY4 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PCDH15 | c.1648G>T p.V550F | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PCDH17 | c.926T>A p.L309Q | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDH8 | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PCDHB8 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 60/668 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDHGA9 | c.1046T>C p.I349T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- PCYOX1L | c.272T>A p.M91K | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PDCD1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE1C | c.1582+1G>T p.X528_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | called by muse, varscan2
- PDE1C | c.1509T>G p.Y503* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | called by muse, varscan2
- PEG3 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PFKM | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGA5 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 164/785 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGLS | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PHEX | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHEX | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- PHGR1 | c.206del p.P69Lfs*39 | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | called by pindel, varscan2
- PIK3AP1 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.5703T>G p.I1901M | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.319); called by muse, mutect2
- PLD3 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- POLK | c.621C>G p.H207Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- POLR3B | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPFIA3 | c.2872G>A p.G958R | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM9 | c.2412T>A p.Y804* | Nonsense Mutation (SNP) | VAF 78/644 reads (12%) | called by muse, varscan2
- PRDX2 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PROM1 | c.2128T>A p.L710M | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRSS35 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRUNE2 | c.1832C>A p.T611K | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PSMD2 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTCRA | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 104/570 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PTGS2 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 48/437 reads (11%) | called by muse, mutect2, varscan2
- PTGS2 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTH2R | c.412-2A>T p.X138_splice | Splice Site (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2075G>T p.S692I | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PUS7L | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3013T>A p.C1005S | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RANBP17 | c.2828A>T p.Y943F | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RASAL1 | c.2223-2A>G p.X741_splice | Splice Site (SNP) | VAF 48/233 reads (21%) | called by muse, mutect2, varscan2
- RASEF | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RASIP1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- RBMXL3 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- RDH14 | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFLNA | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | called by muse, varscan2
- RGS21 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RHOT2 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RIPOR2 | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RNASET2 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- RORB | c.847T>C p.Y283H (on ENST00000396204 / NM_001365023.1; = p.Y272H on NM_006914.4) | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPAP1 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPRD2 | c.2386A>T p.S796C | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RSPH6A | c.853_856dup p.T286Rfs*3 | Frame Shift Ins (INS) | VAF 33/195 reads (17%) | called by mutect2, pindel, varscan2
- RTCA | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1410G>T p.E470D (on ENST00000265814 / NM_001198628.1; = p.E443D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SAMD7 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 197/316 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SCN10A | c.2547G>T p.E849D | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SELENOO | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA3E | c.2101A>T p.S701C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.312); called by muse, mutect2
- SHANK1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC16A6 | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC30A6 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SLC32A1 | c.1405T>C p.C469R | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- SLC36A1 | c.331A>C p.K111Q | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- SLC4A10 | c.167T>A p.L56* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- SMAD9 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMCHD1 | c.716dup p.K240Qfs*30 | Frame Shift Ins (INS) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- SOGA1 | c.906T>A p.D302E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOX8 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SPEN | c.10083G>C p.Q3361H | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPHKAP | c.5062G>T p.G1688W (on ENST00000392056 / NM_001142644.2; = p.G1659W on NM_030623.3) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPHKAP | c.2591C>A p.T864K | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SPOP | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPSB4 | c.628T>A p.Y210N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SRPK2 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- STAB2 | c.5614G>T p.G1872C | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAC2 | c.516C>G p.N172K | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STBD1 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SULT1C2 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUN1 | c.1197G>T p.M399I (on ENST00000405266 / NM_001367651.1; = p.M279I on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/531 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAFA1 | c.70del p.H24Mfs*23 | Frame Shift Del (DEL) | VAF 29/198 reads (15%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TBC1D9B | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBCB | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBX22 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- THNSL2 | c.1448C>G p.S483C | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- TICRR | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2
- TICRR | c.2868A>T p.K956N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM192 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- TMF1 | c.2198C>A p.A733D | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53BP1 | c.5422C>T p.Q1808* | Nonsense Mutation (SNP) | VAF 25/244 reads (10%) | called by muse, mutect2, varscan2
- TPO | c.571T>A p.W191R | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV29DV5 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TRBJ2-1 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
- TRBV27 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRIM67 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 66/416 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); called by muse, varscan2
- TRPC7 | c.797T>G p.L266* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- TSNARE1 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.99010G>C p.D33004H (on ENST00000591111; = p.D25580H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TTN | c.84042C>A p.S28014R (on ENST00000591111; = p.S20590R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | PolyPhen benign (0.022); called by muse, varscan2
- TTN | c.62530G>C p.G20844R (on ENST00000591111; = p.G13420R on NM_003319.4) | Missense Mutation (SNP) | VAF 75/427 reads (18%) | PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TTN | c.48644C>T p.A16215V (on ENST00000591111; = p.A8791V on NM_003319.4) | Missense Mutation (SNP) | VAF 38/146 reads (26%) | PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TTN | c.35027-2A>T p.X11676_splice (on ENST00000591111; = p.X10749_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.22499T>C p.I7500T (on ENST00000591111; = p.I6573T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.18274G>C p.A6092P (on ENST00000591111; = p.A5165P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- TUBB4B | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- UBN2 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UBQLNL | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- USF3 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 158/286 reads (55%) | called by muse, mutect2, varscan2
- USH2A | c.12334G>T p.G4112C | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP11 | c.1784G>T p.R595L (on ENST00000218348; = p.R552L on NM_001371072.1) | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VCAN | c.4222G>T p.V1408L | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- VPS35 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- VPS9D1 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- WDR49 | c.989C>T p.S330L (on ENST00000308378 / NM_001366158.1; = p.S671L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.2624C>G p.T875R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WIZ | c.1452G>T p.R484S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ZCCHC4 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZFAND4 | c.1129A>G p.S377G | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP62 | c.2149A>G p.I717V (on ENST00000502412 / NM_001377944.1; = p.I684V on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZMYM5 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- ZNF14 | c.687del p.A231Pfs*96 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- ZNF227 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF267 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF43 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- ZNF462 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF470 | c.20T>A p.V7E | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- ZNF521 | c.3586C>G p.Q1196E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF549 | c.485del p.K162Rfs*9 (on ENST00000376233 / NM_001199295.2; = p.K149Rfs*9 on NM_153263.2) | Frame Shift Del (DEL) | VAF 44/245 reads (18%) | called by mutect2, pindel, varscan2
- ZNF578 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- ZNF652 | c.1592A>T p.N531I | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF677 | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF677 | c.1183A>G p.R395G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, varscan2
- ZNF677 | c.1111G>T p.G371* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, varscan2
- ZNF677 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF77 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF804B | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNRD2 | c.558_569del p.C187_A190del | In Frame Del (DEL) | VAF 30/138 reads (22%) | called by mutect2, pindel
- AASDH | c.3216G>A p.V1072= | Silent (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- ACACA | c.6372G>A p.E2124= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- ACKR3 | c.96G>T p.V32= | Silent (SNP) | VAF 62/350 reads (18%) | called by muse, mutect2, varscan2
- ACOXL | c.396A>T p.G132= | Silent (SNP) | VAF 39/219 reads (18%) | catalogued as rs763931422; called by muse, mutect2, varscan2
- ACTR5 | c.27C>A p.R9= | Silent (SNP) | VAF 68/438 reads (16%) | catalogued as COSV54759780; called by muse, mutect2
- ADAM8 | c.1443C>A p.G481= | Silent (SNP) | VAF 9/286 reads (3%) | called by muse, mutect2
- ADAM9 | c.726G>T p.L242= | Silent (SNP) | VAF 48/273 reads (18%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.3150G>C p.T1050= | Silent (SNP) | VAF 96/469 reads (20%) | catalogued as COSV99546852; called by muse, mutect2, varscan2
- ADAMTS20 | c.1794C>T p.R598= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- AMFR | c.1290G>T p.A430= | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2
- AMY2A | c.294G>T p.V98= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- ANKS1B | c.493T>C p.L165= | Silent (SNP) | VAF 68/394 reads (17%) | catalogued as rs992396548; called by muse, mutect2, varscan2
- APC2 | c.4194C>T p.V1398= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- ARC | c.615C>T p.P205= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.384C>T p.F128= | Silent (SNP) | VAF 57/285 reads (20%) | catalogued as rs140738674; called by muse, mutect2, varscan2
- ARHGAP39 | c.1389G>T p.T463= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV52766737; called by muse, mutect2, varscan2
- ARNT2 | c.969T>C p.P323= | Silent (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- ASIP | c.31C>T p.L11= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- BCOR | c.2676A>G p.L892= | Silent (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- C16orf82 | c.333G>A p.L111= | Silent (SNP) | VAF 42/401 reads (10%) | catalogued as rs755701144; called by muse, mutect2, varscan2
- C8orf48 | c.627G>T p.L209= | Silent (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- CARS2 | c.1002C>G p.T334= | Silent (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- CBLIF | c.223C>T p.L75= | Silent (SNP) | VAF 96/486 reads (20%) | called by muse, varscan2
- CCDC141 | c.3189G>A p.V1063= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- CD82 | c.459C>T p.V153= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs777519636; called by muse, mutect2, varscan2
- CDC40 | c.1668A>T p.A556= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- CHIA | c.1311C>T p.L437= (on ENST00000343320; = p.L329= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/190 reads (22%) | called by muse, mutect2, varscan2
- CHL1 | c.3267G>T p.A1089= (on ENST00000397491 / NM_001253387.1; = p.A1105= on NM_006614.4) | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- CIC | c.3858T>A p.R1286= | Silent (SNP) | VAF 79/428 reads (18%) | called by muse, mutect2, varscan2
- CLDN19 | c.27G>A p.L9= | Silent (SNP) | VAF 94/441 reads (21%) | catalogued as rs748664372; called by muse, mutect2, varscan2
- CNGA3 | c.561T>A p.I187= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- COL15A1 | c.2430T>C p.H810= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs1268745474; called by muse, mutect2, varscan2
- COL5A1 | c.3960C>T p.A1320= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs1057524173; ClinVar: likely benign; called by muse, mutect2, varscan2
- COMP | c.498G>C p.V166= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CORO7 | c.1965C>A p.V655= | Silent (SNP) | VAF 110/454 reads (24%) | called by muse, mutect2, varscan2
- CPS1 | c.186C>A p.G62= | Silent (SNP) | VAF 32/205 reads (16%) | called by muse, mutect2, varscan2
- DNAAF4 | c.864G>A p.K288= | Silent (SNP) | VAF 29/191 reads (15%) | catalogued as rs1240879469, COSV58247438; called by muse, mutect2, varscan2
- DNAH3 | c.6540C>T p.I2180= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as rs752559320, COSV54545594; called by muse, mutect2, varscan2
- DNAH5 | c.11688C>A p.T3896= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- DPP6 | c.1404C>G p.S468= (on ENST00000377770 / NM_001364500.2; = p.S406= on NM_001936.5) | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- DRGX | c.582C>A p.P194= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- DUSP11 | c.1101C>G p.L367= | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as rs1023366492; called by muse, mutect2, varscan2
- ELAVL3 | c.384C>T p.Y128= | Silent (SNP) | VAF 40/256 reads (16%) | catalogued as rs142817320; called by muse, mutect2, varscan2
- ENTPD2 | c.1356G>T p.P452= (on ENST00000355097 / NM_203468.3; = p.P429= on NM_001246.4) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs762711133; called by muse, mutect2, varscan2
- ERICH3 | c.1053C>T p.T351= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- ERLEC1 | c.789A>C p.S263= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- ERVV-2 | c.687A>T p.P229= | Silent (SNP) | VAF 36/171 reads (21%) | called by mutect2, varscan2
- FAM53C | c.1107G>A p.Q369= | Silent (SNP) | VAF 70/368 reads (19%) | catalogued as rs537387014; called by muse, mutect2, varscan2
- FAM83B | c.927G>T p.S309= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs369793975; called by muse, mutect2, varscan2
- FHOD1 | c.1386G>C p.R462= | Silent (SNP) | VAF 124/305 reads (41%) | called by muse, mutect2, varscan2
- FOXI1 | c.735C>A p.T245= | Silent (SNP) | VAF 81/473 reads (17%) | called by muse, mutect2, varscan2
- FRG2C | c.648G>T p.G216= | Silent (SNP) | VAF 34/528 reads (6%) | called by muse, mutect2
- GARRE1 | c.924G>T p.A308= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- GGT7 | c.750A>G p.P250= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs896653663; called by muse, mutect2, varscan2
- GPR75 | c.1326G>A p.V442= | Silent (SNP) | VAF 43/322 reads (13%) | called by muse, mutect2, varscan2
- GRIN2B | c.2568C>A p.G856= | Silent (SNP) | VAF 46/216 reads (21%) | catalogued as rs1332262298; called by muse, mutect2, varscan2
- H1-2 | c.114C>T p.P38= | Silent (SNP) | VAF 64/281 reads (23%) | catalogued as rs780590605, COSV59189848; called by muse, mutect2, varscan2
- HES4 | c.60C>T p.S20= | Silent (SNP) | VAF 106/378 reads (28%) | catalogued as rs763268705; called by muse, varscan2
- HKDC1 | c.2076C>T p.I692= | Silent (SNP) | VAF 42/218 reads (19%) | catalogued as rs769882307; called by muse, mutect2, varscan2
- HMGN4 | c.249G>C p.A83= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- HS3ST5 | c.867C>A p.T289= | Silent (SNP) | VAF 43/212 reads (20%) | called by muse, mutect2, varscan2
- IFT172 | c.207G>A p.V69= | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- IGF1R | c.1896C>T p.N632= | Silent (SNP) | VAF 67/301 reads (22%) | called by muse, mutect2, varscan2
- IGFBP2 | c.357G>C p.L119= | Silent (SNP) | VAF 57/254 reads (22%) | called by muse, mutect2, varscan2
- INTS1 | c.4503C>G p.L1501= | Silent (SNP) | VAF 84/236 reads (36%) | called by muse, mutect2, varscan2
- IRX4 | c.201C>A p.A67= | Silent (SNP) | VAF 120/554 reads (22%) | called by muse, mutect2, varscan2
- ITIH5 | c.1116C>T p.D372= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs1467684944, COSV53676358; called by muse, varscan2
- ITPR3 | c.2133G>T p.L711= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2
- JUN | c.636C>G p.P212= | Silent (SNP) | VAF 42/131 reads (32%) | called by muse, varscan2
- KLHL13 | c.1962A>T p.A654= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- KNDC1 | c.4914G>C p.A1638= | Silent (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- LARGE1 | c.243G>A p.R81= | Silent (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2, varscan2
- LCT | c.117G>A p.L39= | Silent (SNP) | VAF 46/279 reads (16%) | called by muse, mutect2, varscan2
- LRFN3 | c.1803G>T p.P601= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- LSM11 | c.682C>A p.R228= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs770812064, COSV53848038; called by muse, varscan2
- MAGEB6 | c.777C>T p.G259= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs765918379, COSV100983642; called by muse, mutect2, varscan2
- MAMDC2 | c.909T>C p.F303= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as rs769288620; called by muse, mutect2
- MAN2B2 | c.420T>C p.F140= | Silent (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- MCM3 | c.606C>T p.V202= (on ENST00000229854 / NM_001366374.2; = p.V192= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as COSV57719683; called by muse, mutect2, varscan2
- MEAK7 | c.780G>T p.R260= | Silent (SNP) | VAF 120/294 reads (41%) | called by muse, mutect2, varscan2
- MLXIP | c.2004C>A p.G668= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- MPST | c.51G>C p.A17= (on ENST00000341116 / NM_001369904.2; = p.A37= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- NANOS1 | c.288G>T p.L96= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, varscan2
- NDNF | c.1158A>G p.Q386= | Silent (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- NELFB | c.789C>T p.Y263= | Silent (SNP) | VAF 66/256 reads (26%) | catalogued as rs1351628313; called by muse, mutect2, varscan2
- NKX6-3 | c.243G>T p.G81= | Silent (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- NMBR | c.135G>T p.V45= | Silent (SNP) | VAF 91/495 reads (18%) | called by muse, mutect2, varscan2
- NPAP1 | c.2073C>G p.S691= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- NPHS1 | c.255G>A p.L85= | Silent (SNP) | VAF 18/494 reads (4%) | catalogued as rs1192855645, COSV100800213; called by muse, mutect2
- OGDHL | c.2292G>A p.L764= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- OPLAH | c.648G>C p.V216= | Silent (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
- OR11H2 | c.618A>G p.L206= (on ENST00000556246; = p.L217= on NM_001197287.1) | Silent (SNP) | VAF 94/456 reads (21%) | catalogued as rs531421714; called by muse, mutect2, varscan2
- OR2AJ1 | c.546T>A p.P182= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- OR4C16 | c.630C>G p.V210= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100113841, COSV58942851; called by muse, mutect2, varscan2
- OR51B4 | c.387C>T p.Y129= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs1433092430; called by muse, mutect2, varscan2
- OR5F1 | c.319C>T p.L107= | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as rs780714469; called by muse, mutect2, varscan2
- OR5M10 | c.142C>T p.L48= | Silent (SNP) | VAF 78/436 reads (18%) | called by muse, mutect2, varscan2
- OR8G5 | c.780G>C p.L260= | Silent (SNP) | VAF 67/308 reads (22%) | called by muse, varscan2
- PCDHA7 | c.1824G>A p.S608= | Silent (SNP) | VAF 16/517 reads (3%) | catalogued as COSV65341577, COSV65342370; called by muse, mutect2
- PCDHB3 | c.1221C>A p.G407= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV50567073; called by muse, mutect2, varscan2
- PDZD2 | c.3285C>G p.T1095= | Silent (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- PGAP6 | c.840G>C p.V280= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PIGG | c.726G>T p.V242= | Silent (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- PITPNM1 | c.2340C>G p.S780= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PKP3 | c.1659C>G p.R553= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- PNPLA6 | c.1374G>T p.L458= (on ENST00000414982 / NM_001166111.2; = p.L410= on NM_006702.5) | Silent (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- PODN | c.768G>A p.L256= (on ENST00000395871; = p.L208= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/233 reads (6%) | called by muse, mutect2
- PTBP2 | c.1446G>T p.L482= (on ENST00000426398 / NM_001300986.2; = p.L474= on NM_021190.4) | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- PTPRS | c.1626G>T p.T542= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- PXDNL | c.2493G>T p.P831= | Silent (SNP) | VAF 63/248 reads (25%) | catalogued as COSV100681216, COSV62481028; called by muse, mutect2, varscan2
- RANBP2 | c.7233T>C p.D2411= | Silent (SNP) | VAF 132/742 reads (18%) | catalogued as rs751641605; called by muse, mutect2, varscan2
- RASGRF1 | c.2703G>T p.S901= | Silent (SNP) | VAF 54/356 reads (15%) | called by muse, mutect2, varscan2
- RBM17 | c.513C>G p.G171= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- RTN1 | c.747C>T p.I249= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs866905216, COSV50718958, COSV50727806; called by muse, mutect2, varscan2
- RYR3 | c.603C>G p.L201= | Silent (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- SAGE1 | c.2685C>T p.L895= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV61018121; called by muse, varscan2
- SALL3 | c.3360G>A p.K1120= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- SCART1 | c.2460G>T p.A820= | Silent (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- SCN10A | c.306C>A p.S102= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV71860990; called by muse, mutect2, varscan2
- SEPTIN7 | c.1305G>A p.K435= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- SERPINI1 | c.36G>A p.L12= | Silent (SNP) | VAF 60/330 reads (18%) | called by muse, mutect2, varscan2
- SHANK2 | c.2421G>A p.P807= | Silent (SNP) | VAF 1097/1550 reads (71%) | catalogued as rs782015393; called by muse, mutect2, varscan2
- SIRPA | c.1464G>A p.K488= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- SIRT6 | c.642T>A p.G214= | Silent (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- SLC12A2 | c.165G>C p.G55= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1284706920; called by muse, mutect2, varscan2
- SLC22A11 | c.591C>T p.C197= | Silent (SNP) | VAF 65/280 reads (23%) | catalogued as rs765684660, COSV57254474; called by muse, mutect2, varscan2
- SLC39A12 | c.1461C>A p.S487= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- SLC6A19 | c.1422G>T p.T474= | Silent (SNP) | VAF 150/590 reads (25%) | catalogued as rs544821069; called by muse, mutect2, varscan2
- SLIT2 | c.2373G>T p.T791= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs375099406, COSV56586651; called by muse, mutect2, varscan2
- SPATA20 | c.2055G>T p.V685= (on ENST00000356488 / NM_001258372.1; = p.V701= on NM_022827.4) | Silent (SNP) | VAF 105/513 reads (20%) | called by muse, mutect2, varscan2
- SPOP | c.450C>T p.L150= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- STAC3 | c.780C>G p.A260= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as COSV60416028; called by muse, mutect2, varscan2
- TAF4 | c.1656G>T p.L552= | Silent (SNP) | VAF 57/267 reads (21%) | called by muse, mutect2, varscan2
- TCEAL1 | c.36G>A p.P12= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV101010130; called by muse, mutect2, varscan2
- THAP12 | c.681G>T p.T227= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- TMEM182 | c.402C>A p.I134= | Silent (SNP) | VAF 42/238 reads (18%) | catalogued as COSV68425480; called by muse, mutect2, varscan2
- TTN | c.84195C>T p.Y28065= (on ENST00000591111; = p.Y20641= on NM_003319.4) | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, varscan2
- UNC5A | c.726C>T p.D242= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs752732030; called by muse, mutect2, varscan2
- USP53 | c.1665C>T p.G555= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs1465111594; called by muse, mutect2, varscan2
- ZBED5 | c.1812G>C p.V604= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- ZC3H11A | c.1878G>C p.G626= | Silent (SNP) | VAF 52/411 reads (13%) | called by muse, mutect2, varscan2
- ZHX1 | c.1281G>A p.Q427= | Silent (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- ZIC3 | c.63G>C p.A21= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV54975067; called by muse, mutect2, varscan2
- ZIM2 | c.1197C>T p.L399= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as COSV99687037; called by muse, mutect2, varscan2
- ZMAT4 | c.645C>A p.A215= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs760349043; called by muse, mutect2, varscan2
- ZNF236 | c.2868G>A p.L956= | Silent (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- ZNF462 | c.2073G>A p.K691= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- ZNF521 | c.175C>T p.L59= | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as rs759818586; called by muse, mutect2, varscan2
- ZNF665 | c.798A>T p.S266= (on ENST00000600412; = p.S331= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- ZNF716 | c.663C>T p.S221= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV70783098; called by muse, mutect2, varscan2
- ZNF99 | c.1176T>C p.T392= | Silent (SNP) | VAF 33/224 reads (15%) | catalogued as COSV68056658; called by muse, mutect2, varscan2
- ZRANB3 | c.1410G>C p.L470= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- ZXDC | c.159G>A p.A53= | Silent (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- A1BG | c.*8G>A | 3'UTR (SNP) | VAF 49/244 reads (20%) | catalogued as COSV54051565, COSV99568719; called by muse, mutect2, varscan2
- AC092865.4 | n.139C>T | RNA (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- ACSF3 | c.1366+3504C>T | Intron (SNP) | VAF 120/292 reads (41%) | called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084884 G>T | 5'Flank (SNP) | VAF 91/456 reads (20%) | called by muse, mutect2, varscan2
- ADIG | c.125-524G>A | Intron (SNP) | VAF 25/90 reads (28%) | catalogued as COSV64893998; called by muse, mutect2, varscan2
- AOPEP | c.2115+387T>G | Intron (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- AP002495.1 | c.436+341G>A | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915763 A>T | 5'Flank (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- C12orf43 | c.188+72G>T | Intron (SNP) | VAF 49/240 reads (20%) | catalogued as rs747554465; called by muse, mutect2, varscan2
- CATSPER1 | c.*21C>G | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- CCDC144CP | n.3768T>C | RNA (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- CDRT15P3 | n.481T>A | RNA (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- CELF6 | c.-208C>A | 5'UTR (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
- CEP41 | c.*1655G>T | 3'UTR (SNP) | VAF 38/193 reads (20%) | called by muse, mutect2, varscan2
- CHRNA4 | c.76+15G>A | Intron (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- COL5A1 | c.2332-43C>G | Intron (SNP) | VAF 50/247 reads (20%) | called by muse, mutect2, varscan2
- CTBP1 | c.195+204G>C | Intron (SNP) | VAF 41/175 reads (23%) | catalogued as COSV99337886; called by muse, mutect2, varscan2
- DAO | chr12:108879602 A>T | 5'Flank (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- DCBLD2 | c.1720+10G>C | Intron (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- DCBLD2 | c.1720+9C>T | Intron (SNP) | VAF 41/85 reads (48%) | catalogued as rs758474961; called by muse, mutect2, varscan2
- DUSP22 | c.508+38C>A | Intron (SNP) | VAF 33/404 reads (8%) | catalogued as rs372511254; called by muse, mutect2
- EGR2 | c.*38C>T | 3'UTR (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99654288; called by muse, mutect2, varscan2
- EMC10 | chr19:50476506 G>T | 5'Flank (SNP) | VAF 49/268 reads (18%) | called by muse, mutect2, varscan2
- ENTPD1 | c.16+47A>T | Intron (SNP) | VAF 23/140 reads (16%) | catalogued as rs369264187; called by muse, mutect2
- ENTPD1 | c.573+49C>G | Intron (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2350-2845C>T | Intron (SNP) | VAF 10/54 reads (19%) | catalogued as rs142925857; called by muse, varscan2
- FAM151B | chr5:80488078 A>T | 5'Flank (SNP) | VAF 70/302 reads (23%) | called by muse, mutect2, varscan2
- FCGR3B | c.-44-27C>A | Intron (SNP) | VAF 52/316 reads (16%) | called by muse, mutect2, varscan2
- FOLH1B | n.1626G>C | RNA (SNP) | VAF 51/296 reads (17%) | catalogued as rs769447971; called by muse, mutect2, varscan2
- FZD6 | c.*45G>C | 3'UTR (SNP) | VAF 65/239 reads (27%) | called by muse, mutect2
- FZD6 | c.*47A>T | 3'UTR (SNP) | VAF 62/234 reads (26%) | called by muse, mutect2
- GBA3 | c.59-8484C>A | Intron (SNP) | VAF 62/334 reads (19%) | called by muse, mutect2, varscan2
- GRM6 | c.2436+14C>T | Intron (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- HERC2P3 | n.869G>A | RNA (SNP) | VAF 47/359 reads (13%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1730+574C>A | Intron (SNP) | VAF 56/214 reads (26%) | catalogued as COSV58089169; called by muse, mutect2, varscan2
- HSP90B3P | n.31T>A | RNA (SNP) | VAF 64/323 reads (20%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937680 del C | 3'Flank (DEL) | VAF 56/297 reads (19%) | called by mutect2, varscan2
- LINC02249 | n.187G>A | RNA (SNP) | VAF 43/336 reads (13%) | called by muse, mutect2, varscan2
- LINC02312 | n.608C>A | RNA (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- MASP1 | c.1304-5035C>A | Intron (SNP) | VAF 34/232 reads (15%) | called by muse, mutect2, varscan2
- MYB | c.1203+762G>T | Intron (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- MYD88 | c.464-36G>A | Intron (SNP) | VAF 97/346 reads (28%) | catalogued as rs560025144; called by muse, mutect2, varscan2
- MYT1 | c.1847-54C>A | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- NBN | c.*70A>G | 3'UTR (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18339531 G>A | 5'Flank (SNP) | VAF 32/290 reads (11%) | called by mutect2, varscan2
- OR10D1P | n.343G>A | RNA (SNP) | VAF 47/221 reads (21%) | catalogued as rs887472222; called by muse, mutect2, varscan2
- OR2W5 | n.1215A>G | RNA (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- PFKFB3 | c.1341+371G>A | Intron (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- RAB22A | c.-19C>G | 5'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- RAB3GAP1 | c.*994A>G | 3'UTR (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- RBM39 | c.52-449C>A | Intron (SNP) | VAF 49/241 reads (20%) | called by muse, mutect2, varscan2
- RBM43 | c.3+253G>T | Intron (SNP) | VAF 108/472 reads (23%) | called by muse, mutect2, varscan2
- RFK | chr9:76398792 T>G | 5'Flank (SNP) | VAF 56/341 reads (16%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159235 C>G | 5'Flank (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159612 G>T | 5'Flank (SNP) | VAF 19/113 reads (17%) | catalogued as rs750959972; called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13311C>A | Intron (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- RUSF1 | c.*581C>A | 3'UTR (SNP) | VAF 126/552 reads (23%) | called by muse, mutect2, varscan2
- SLCO4A1 | chr20:62642213 C>T | 5'Flank (SNP) | VAF 15/366 reads (4%) | catalogued as rs1445938081; called by muse, mutect2
- SNORD115-13 | n.80C>G | RNA (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- SPANXB1 | c.-15G>A | 5'UTR (SNP) | VAF 74/1138 reads (7%) | called by muse, mutect2
- SPEF2 | c.5379+460T>A | Intron (SNP) | VAF 46/223 reads (21%) | called by muse, mutect2, varscan2
- SPTA1 | c.6789-35A>G | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- SRD5A1 | c.294-6961G>T | Intron (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- STARD8 | c.-7-994A>T | Intron (SNP) | VAF 22/63 reads (35%) | catalogued as rs1291170932; called by muse, mutect2, varscan2
- TAT | c.1225-42A>G | Intron (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.435G>A | RNA (SNP) | VAF 38/383 reads (10%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2619-13T>A | Intron (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- TMEM241 | c.*1A>G | 3'UTR (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- TMEM252 | c.*54_*55insC | 3'UTR (INS) | VAF 28/178 reads (16%) | called by mutect2, pindel, varscan2
- TMEM255A | c.424-218C>A | Intron (SNP) | VAF 19/47 reads (40%) | catalogued as COSV59031959; called by muse, mutect2, varscan2
- TPSD1 | chr16:1261455 G>T | 3'Flank (SNP) | VAF 44/187 reads (24%) | called by muse, mutect2, varscan2
- TTYH1 | c.-44C>A | 5'UTR (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2
- TUBB7P | n.1047A>G | RNA (SNP) | VAF 20/253 reads (8%) | called by muse, mutect2
- TUT1 | chr11:62574716 G>C | 3'Flank (SNP) | VAF 45/241 reads (19%) | called by muse, mutect2, varscan2
- WHRN | c.*36C>T | 3'UTR (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- ZIC4 | c.-16+931C>A | Intron (SNP) | VAF 68/252 reads (27%) | called by muse, mutect2, varscan2
- ZNF213 | chr16:3146004 C>A | 3'Flank (SNP) | VAF 51/261 reads (20%) | called by muse, mutect2, varscan2
- ZNF599 | c.-15C>A | 5'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2
- ZNF626 | c.*39G>A | 3'UTR (SNP) | VAF 39/187 reads (21%) | catalogued as COSV101657017; called by muse, mutect2, varscan2
- ZNF812P | n.709G>T | RNA (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- ZNF849P | n.1023A>T | RNA (SNP) | VAF 54/285 reads (19%) | called by muse, mutect2, varscan2
- ZNF98 | c.-34T>A | 5'UTR (SNP) | VAF 51/309 reads (17%) | called by muse, mutect2, varscan2
